Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7395, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7395-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) MENTAL NERVE MARGIN, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 2) ANTERIOR GINGIVAL, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 3) MOUTH, RIGHT BUCCAL, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 4) PALATE, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 5) PHARYNX, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 6) FLOOR OF MOUTH, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 7) TONGUE, RIGHT, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 8) MANDIBULAR GINGIVA, RIGHT, RESECTION: INVASIVE MODERATELY-DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.0 CM IN GREATEST DIMENSION, 3.0 MM TO INFERIOR MARGIN; PERINEURAL INVASION NOT IDENTIFIED; ALL FINAL SURGICAL MARGINS NEGATIVE FOR MALIGNANCY; (SEE COMMENT).
- 9) SUBMANDIBULAR GLAND, RIGHT, RESECTION: NEGATIVE FOR MALIGNANCY.

COMMENT: This tumor corresponds to AJCC pathologic stage II (pT2). HPV in situ hybridization studies were sent (please see separate report).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Incisional and Excisional Biopsy, Resection

Note: Check 1 response unless otherwise indicated.

MACROSCOPIC

Specimen Type

- ☐ Incisional biopsy
- ☐ Excisional biopsy
- ☒ Resection (specify type): gingival resection
- ☐ Other (specify): _____
- ☐ Not specified

Tumor Site (check all that apply)

☐ Lip

[REDACTED]

[page 2 of 6]
- X Oral cavity
___ Pharynx, oropharynx
___ Pharynx, hypopharynx
___ Pharynx, nasopharynx
___ Larynx, supraglottis
___ Larynx, glottis
___ Larynx, subglottis
___ Paranasal sinus(es), maxillary
___ Paranasal sinus(es), ethmoid
___ Other (specify): _____
___ Not specified

Tumor Size

Greatest dimension: 3.0 cm

*Additional dimensions: 1.5 x 1.0 cm

MICROSCOPIC

Histologic Type

Carcinomas of the Upper Aerodigestive Tract

- X Squamous cell carcinoma, conventional

Histologic Grade

- ___ Not applicable
___ GX: Cannot be assessed
___ G1: Well differentiated
X G2: Moderately differentiated
___ G3: Poorly differentiated
___ Other (specify): _____

Primary Tumor (pT): Lip and Oral Cavity

- ___ pTX: Cannot be assessed
___ pT0: No evidence of primary tumor
___ pTis: Carcinoma in situ
___ pT1: Tumor 2 cm or less in greatest dimension
X pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension
___ pT3: Tumor more than 4 cm in greatest dimension
___ pT4: Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose
___ pT4a: Oral cavity: Tumor invades adjacent structures (eg, through cortical bone, into deep [extrinsic] muscle of tongue [genioglossus, hyoglossus, palatoglossus, and styloglossus], maxillary sinus, skin of face)
___ pT4b: Tumor invades masticator space, pterygoid plates, or skull base, and/or encases internal carotid artery

Regional Lymph Nodes (pN): All Aerodigestive Sites Except Nasopharynx

- X pNX: Cannot be assessed
___ pN0: No regional lymph node metastasis
___ pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension

[page 3 of 6]
___ pN2a: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension
___ pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension
___ pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension
___ pN3: Metastasis in a lymph node more than 6 cm in greatest dimension
Specify: Number examined: ___
Number involved: ___

Distant Metastasis (pM)

X pMX: Cannot be assessed
___ pM1: Distant metastasis
*Specify site(s), if known: _____

Margins (check all that apply)

___ Cannot be assessed
X Margins uninvolved by tumor
Distance of tumor from closest margin: 3.0 mm
Specify margin, if possible: inferior
X Carcinoma in situ absent
___ Carcinoma in situ present
___ Carcinoma in situ, not applicable

*Venous/Lymphatic (Large/Small Vessel) Invasion (V/L)

*X Absent
* ___ Present
* ___ Indeterminate

Perineural Invasion

X Absent
___ Present

**Electronically Signed Out by

CLINICAL DATA

Clinical Features: unspecified

Operator: Dr. _____

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) right mental nerve margin, 2) right anterior gingiva margin, 3) right buccal margin, 4) right palate margin, 5) right pharyngeal margin, 6) right floor of mouth margin, 7) right tongue margin 8) right mandibular gingival, 9) right submandibular gland
high risk HPVISH and P16IHC

[page 4 of 6]
GROSS DESCRIPTION:

1) SOURCE: Nerve, Right Mental Margin

Received fresh for frozen section labeled "right mental nerve margin" are fragments of soft tissue measuring 0.3 x 0.4 cm in aggregate. The specimen is entirely submitted for frozen section.

Summary of sections: 1AFSC, 2/1.

2) SOURCE: Right Anterior Gingiva Margin

Received fresh labeled "right anterior gingiva margin" is a strip of pink-tan soft tissue measuring 0.9 x 0.3 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Right Buccal Margin

Received fresh labeled "right buccal margin" is a pink-tan strip of soft tissue measuring 7.5 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Palate, Right Margin

Received fresh labeled "right palate margin" is a pink-tan strip of soft tissue measuring 4.8 x 0.3 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections: 4AFSC, 1/1.

5) SOURCE: Pharynx, Right Margin

Received fresh labeled "right pharyngeal margin" is a strip of pink-tan soft tissue measuring 4.1 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections: 5AFSC, 1/1.

6) SOURCE: Mouth, Right Floor Of, Margin

Received fresh labeled "right floor of mouth margin" is a strip of pink-tan soft tissue measuring 3.9 x 0.4 x 0.3 cm. The specimen is submitted entirely for frozen section.

Summary of sections: 6AFSC, 1/1.

7) SOURCE: Tongue, Right Margin

Received fresh labeled "right tongue margin" are fragments of pink-tan soft tissue measuring from 0.4 to 3.1 cm.

Summary of sections: 7AFSC, 3/1; 7BFSC, 3/1.

8) SOURCE: Right Mandibular Gingival

Received fresh labeled "right mandibular gingival cancer-stitch=anterior (perm)" is an oriented piece of oral mucosa with a central mass. The

[page 5 of 6]
specimen is oriented with a stitch at the anterior side so it is inked in the following fashion: anterior-orange, posterior-black, inferior-green, superior-lingual mucosa itself, medial-red, lateral-blue. The specimen measures 5.5 x 3.5 x 2.2 cm. There is a discrete fungating mass in the center of the specimen that measures 3.0 x 1.5 x 1.0 cm. The specimen is sectioned from anterior to posterior. Deep to the mass the tissue is soft and light tan. In the middle of the lesion there is a nodule that is white and measures 0.3 cm in circumference. This ill-defined mass does not have a clear border but does not appear to be involving the inferior margin grossly. The specimen is sectioned from anterior to posterior and submitted in its entirety.

Summary of sections: 8A, anterior end, 2/1; 8B-8C, normal mucosa, 1/1 each; 8D-8L, mass, 1/1 each; 8M-8N, normal mucosa, 1/1 each; 8O, posterior end, 1/1.

9) SOURCE: Right Submandibular Gland

Received fresh labeled "right submandibular gland" is an unoriented tan salivary gland measuring 4.5 x 2.6 x 1.1 cm. There are no masses visible externally. The exterior is inked. The specimen is sectioned to reveal homogenous tan parenchyma without any masses or lesions. Representative sections are submitted.

Summary of sections: 9A-9C, 1/1 each.

Dictated by [REDACTED]

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Nerve, Right Mental Margin

FROZEN SECTION DIAGNOSIS: BENIGN NERVE. [REDACTED]

2) SOURCE: Right Anterior Gingiva Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Right Buccal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Palate, Right Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

5) SOURCE: Pharynx, Right Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

6) SOURCE: Mouth, Right Floor Of, Margin

[page 6 of 6]
FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

7) SOURCE: Tongue, Right Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

Electronically signed by: [REDACTED], Attending Pathologist

ADDENDUM FINDINGS:

HPV studies as performed by Dr. [REDACTED]
Reference Laboratories shows the tumor to be P16 negative by
immunohistochemistry and HPV 16 negative by in-situ hybridization.

[REDACTED] /

Electronically signed by [REDACTED]

Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file 89f09156-e4b3-49a8-91ae-bc338c9b7034 (TCGA-CR-7395.4DEFBDD8-2306-48FA-A6FD-2085E99534EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).